Gene-level copy-number profile of tumor specimen TCGA-69-8253-01A from TCGA case TCGA-69-8253, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.6 years (21,771 days).
Specimen TCGA-69-8253-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4eb9e983-d265-4149-ba13-45f90f4af7d3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-8253-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c57c1dd-337c-4e9e-8443-95fb61584b27

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 51; copy number 2: 13,500; copy number 3: 30,003; copy number 4: 8,154; copy number 5: 4,454; copy number 6: 3,114; copy number 7: 529; copy number 9: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-8253-01A-11D-2283-01): tumor purity 0.39, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 543 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:7,965,310–8,516,759, 14 genes, copy number 9: ABLIM2, MIR95, AC097381.3, AC097381.2, GMPSP1, SH3TC1, HTRA3, LINC02517, AC104825.1, ACOX3, RNA5SP152, TRMT44, AC105345.2, AC105345.1.
- chr20:87,250–25,969,288, 529 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
